Somatic mutation profile of cancer-model specimen HCM-BROD-0104-C71-85B (Adherent Cell Line, passage 7; aliquot HCM-BROD-0104-C71-85B-01D-A78T-36), derived from the primary tumor of HCMI case HCM-BROD-0104-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.0 years (23,020 days).
Specimen HCM-BROD-0104-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52f18b23-af9c-497e-a7c7-64c984c4ae8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0104-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0104-C71-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ba1ce5d-ac04-4359-8711-2059125207ca

The open-access MAF lists 102 somatic variants for this specimen: 68 protein-altering or splice-affecting, 23 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 23, Intron 7, Nonsense Mutation 4, Frame Shift Del 3, In Frame Del 1, Splice Region 1, 5'Flank 1, 3'UTR 1, RNA 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1351_1356del p.E451_Y452del (on ENST00000521381 / NM_181523.3; = p.E181_Y182del on NM_181504.4) | In Frame Del (DEL) | VAF 15/40 reads (38%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ADAM32 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs767287185; called by muse, mutect2, varscan2
- ADPRS | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 167/331 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs1398056859; called by muse, mutect2, varscan2
- AFF1 | c.1874G>A p.R625K | Missense Mutation (SNP) | VAF 80/164 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV57117673; called by muse, mutect2, varscan2
- AGBL1 | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 33/66 reads (50%) | catalogued as rs544094832, COSV66849419; called by muse, mutect2, varscan2
- ANKRD65 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 142/232 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368780971; called by muse, mutect2, varscan2
- ARHGEF5 | c.3898G>A p.V1300I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs1360049836; called by mutect2, varscan2
- BCLAF1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as COSV62140394; called by muse, mutect2, varscan2
- BCLAF1 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62140517; called by muse, mutect2, varscan2
- BPIFA1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 175/577 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs6120181; called by muse, mutect2, varscan2
- CCSER1 | c.2296C>A p.R766S | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.066); catalogued as rs569829898, COSV61446572; called by muse, mutect2, varscan2
- CD1E | c.431G>C p.G144A | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63770040; called by muse, mutect2, varscan2
- CDNF | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 84/85 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101012365; called by muse, mutect2, varscan2
- CGNL1 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 91/230 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs372428898; called by muse, mutect2, varscan2
- DAAM2 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 219/428 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1390440173, COSV51417930, COSV51419283; called by muse, varscan2
- EMD | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1169279026; called by muse, mutect2, varscan2
- ERICH6 | c.1209C>G p.N403K | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762527505, COSV55803675; called by muse, mutect2, varscan2
- FREM1 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 169/373 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs369488195, COSV66527572; called by muse, mutect2, varscan2
- FRMD4B | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201890981; called by muse, mutect2, varscan2
- G6PC | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.144); catalogued as rs367727229, CM980787; called by muse, mutect2, varscan2
- HIF3A | c.1243C>T p.R415C (on ENST00000377670 / NM_152795.4; = p.R346C on NM_022462.4) | Missense Mutation (SNP) | VAF 44/327 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1039626444, COSV99355793; called by muse, mutect2, varscan2
- HSD3B2 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 60/291 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs748851282, COSV101027530; called by muse, mutect2, varscan2
- ISYNA1 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 57/581 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV53214078; called by muse, mutect2
- KCNK1 | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.247); catalogued as rs1400981676, COSV64035238; called by muse, mutect2, varscan2
- MAP3K9 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 99/230 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751015012, COSV67122589; called by muse, mutect2, varscan2
- MS4A14 | c.662C>A p.P221Q | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.703); catalogued as COSV100280409; called by muse, mutect2, varscan2
- OIT3 | c.1282G>A p.G428S | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); catalogued as rs140962729; called by muse, mutect2, varscan2
- OR2T2 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 32/194 reads (16%) | catalogued as rs759702597, COSV100737533; called by mutect2, varscan2
- PCLO | c.9824G>A p.R3275Q | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1562876553, COSV104415074, COSV61633321; called by muse, mutect2, varscan2
- PPA1 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs146821187; called by muse, mutect2, varscan2
- PTPRR | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 155/352 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.207); catalogued as rs567626445, COSV51726651, COSV99315904; called by muse, mutect2, varscan2
- SLC5A4 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 131/331 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs755635977, COSV56670823; called by muse, mutect2, varscan2
- SLC5A8 | c.1691A>G p.N564S | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.11); catalogued as rs1177418877; called by muse, mutect2, varscan2
- TNPO2 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 10/237 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs937164324, COSV63510030; called by muse, mutect2
- TSHZ2 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs367984099; called by muse, mutect2, varscan2
- ZNF251 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as rs773135594, COSV52959513; called by muse, mutect2, varscan2
- ZNF33B | c.2063C>T p.T688M | Missense Mutation (SNP) | VAF 100/101 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs751588162; called by muse, mutect2, varscan2
- ZNF347 | c.729C>G p.I243M | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.033); catalogued as COSV100498438; called by muse, mutect2, varscan2
- ZNF99 | c.1804T>G p.F602V | Missense Mutation (SNP) | VAF 106/584 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV68055953; called by muse, varscan2
- ZP4 | c.878C>G p.S293C | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.796); catalogued as rs377492296, COSV100850766; called by muse, mutect2, varscan2
- ANKRD30B | c.3233A>G p.N1078S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ANKRD54 | c.377-1G>A p.X126_splice | Splice Site (SNP) | VAF 120/231 reads (52%) | called by muse, mutect2, varscan2
- ARHGEF35 | c.1372T>C p.C458R | Missense Mutation (SNP) | VAF 79/370 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- BCLAF1 | c.798G>C p.Q266H | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- CCDC141 | c.3626T>C p.V1209A | Missense Mutation (SNP) | VAF 137/274 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCNF | c.742_743del p.R248Gfs*33 | Frame Shift Del (DEL) | VAF 130/346 reads (38%) | called by mutect2, pindel, varscan2
- CEL | c.803G>A p.G268D (on ENST00000673714; = p.G265D on NM_001807.6) | Missense Mutation (SNP) | VAF 280/575 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- DCAF8L2 | c.1168T>A p.F390I | Missense Mutation (SNP) | VAF 111/203 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GNL3L | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 64/199 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GRM1 | c.528G>T p.Q176H | Missense Mutation (SNP) | VAF 223/449 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMGB3 | c.455A>C p.K152T | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- IRAK3 | c.1018T>C p.Y340H | Missense Mutation (SNP) | VAF 93/162 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ISL1 | c.659T>A p.L220H | Missense Mutation (SNP) | VAF 232/467 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KEL | c.1315-5C>A | Splice Region (SNP) | VAF 217/671 reads (32%) | called by muse, mutect2, varscan2
- LRP1 | c.5587C>T p.P1863S | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LYL1 | c.597C>G p.I199M | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO1B | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 43/120 reads (36%) | called by muse, mutect2, varscan2
- NADSYN1 | c.443A>T p.Q148L | Missense Mutation (SNP) | VAF 12/285 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.143); called by muse, mutect2
- NF1 | c.296del p.K99Rfs*4 | Frame Shift Del (DEL) | VAF 39/109 reads (36%) | called by mutect2, pindel, varscan2
- NFYC | c.1199G>A p.R400K | Missense Mutation (SNP) | VAF 160/347 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NTAQ1 | c.118A>G p.K40E | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- OR8B8 | c.802A>C p.M268L | Missense Mutation (SNP) | VAF 10/291 reads (3%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2
- P2RY4 | c.853A>C p.N285H | Missense Mutation (SNP) | VAF 137/303 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RIMS2 | c.4330G>C p.V1444L (on ENST00000666250 / NM_001348490.2; = p.V1015L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- RPGRIP1L | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 119/227 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RYR3 | c.11047del p.S3683Lfs*12 (on ENST00000389232; = p.S3684Lfs*12 on NM_001036.6) | Frame Shift Del (DEL) | VAF 38/98 reads (39%) | called by mutect2, pindel, varscan2
- SYTL5 | c.959C>G p.S320* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- ZNF347 | c.524C>G p.A175G | Missense Mutation (SNP) | VAF 68/235 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ACY3 | c.852C>T p.N284= | Silent (SNP) | VAF 289/605 reads (48%) | catalogued as rs146627401; called by muse, mutect2, varscan2
- ADAD2 | c.159C>T p.R53= | Silent (SNP) | VAF 45/84 reads (54%) | catalogued as rs1360227408, COSV51895041; called by muse, mutect2, varscan2
- CACNA1E | c.312C>T p.I104= | Silent (SNP) | VAF 107/253 reads (42%) | catalogued as rs760287778; called by muse, mutect2, varscan2
- CD80 | c.258G>A p.E86= | Silent (SNP) | VAF 86/372 reads (23%) | called by muse, mutect2, varscan2
- CHSY1 | c.1692C>T p.N564= | Silent (SNP) | VAF 6/83 reads (7%) | catalogued as rs1156457555; called by muse, mutect2
- IDS | c.357C>T p.I119= | Silent (SNP) | VAF 131/296 reads (44%) | catalogued as rs782362742; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIDINS220 | c.4690A>C p.R1564= | Silent (SNP) | VAF 59/145 reads (41%) | called by muse, mutect2, varscan2
- MMP13 | c.840G>A p.T280= | Silent (SNP) | VAF 50/309 reads (16%) | catalogued as rs782436272; called by muse, mutect2, varscan2
- NUP107 | c.156C>T p.I52= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs1303882637; called by muse, mutect2, varscan2
- PLEKHG6 | c.205C>T p.L69= | Silent (SNP) | VAF 108/239 reads (45%) | called by muse, mutect2, varscan2
- PLEKHH3 | c.1080C>T p.T360= | Silent (SNP) | VAF 87/168 reads (52%) | catalogued as COSV52219673, COSV99257894; called by muse, mutect2, varscan2
- PLOD1 | c.729C>T p.N243= | Silent (SNP) | VAF 87/135 reads (64%) | catalogued as rs567164584, COSV52140360; called by muse, mutect2, varscan2
- PPL | c.1839G>A p.V613= | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as rs1286670495; called by muse, mutect2, varscan2
- PRR16 | c.729G>A p.K243= (on ENST00000407149 / NM_001300783.2; = p.K220= on NM_016644.2) | Silent (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- REV1 | c.2733G>A p.G911= | Silent (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- SAMSN1 | c.516G>A p.T172= | Silent (SNP) | VAF 53/262 reads (20%) | catalogued as rs745867626, COSV53467189; called by muse, mutect2, varscan2
- SIX5 | c.396G>A p.L132= | Silent (SNP) | VAF 74/260 reads (28%) | called by muse, mutect2, varscan2
- SKI | c.375G>A p.Q125= | Silent (SNP) | VAF 113/485 reads (23%) | called by muse, mutect2, varscan2
- SLC6A4 | c.819C>T p.G273= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs200745147; called by muse, mutect2, varscan2
- SPAM1 | c.354T>C p.I118= | Silent (SNP) | VAF 16/159 reads (10%) | called by muse, mutect2, varscan2
- WASHC4 | c.3042T>C p.Y1014= | Silent (SNP) | VAF 31/168 reads (18%) | called by muse, mutect2, varscan2
- ZNF347 | c.1062C>T p.F354= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as rs769820418; called by muse, mutect2, varscan2
- ZSCAN10 | c.1785G>A p.A595= (on ENST00000252463; = p.A650= on NM_032805.3) | Silent (SNP) | VAF 120/245 reads (49%) | catalogued as rs1303958259, COSV52966844; called by muse, mutect2, varscan2
- AC133561.1 | n.1376T>C | RNA (SNP) | VAF 123/280 reads (44%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503673 del TGTC | 5'Flank (DEL) | VAF 6/29 reads (21%) | catalogued as rs751652054; called by mutect2, pindel, varscan2
- AP2A2 | c.67+14753C>A | Intron (SNP) | VAF 98/229 reads (43%) | catalogued as rs751886019; called by muse, mutect2, varscan2
- C8orf34 | c.1106-14731C>T | Intron (SNP) | VAF 30/78 reads (38%) | catalogued as rs761266402, COSV57395926; called by muse, mutect2, varscan2
- IQSEC2 | c.737+12349C>G | Intron (SNP) | VAF 24/96 reads (25%) | called by muse, varscan2
- MMP9 | c.1902-13C>T | Intron (SNP) | VAF 159/541 reads (29%) | catalogued as rs1384158377, COSV63434234; called by muse, mutect2, varscan2
- MYF6 | c.*28C>T | 3'UTR (SNP) | VAF 16/264 reads (6%) | catalogued as rs1448278101; called by muse, mutect2
- PSG6 | chr19:42902435 C>A | 3'Flank (SNP) | VAF 50/219 reads (23%) | called by muse, varscan2
- RANGRF | c.438-50A>G | Intron (SNP) | VAF 59/139 reads (42%) | called by muse, mutect2, varscan2
- TTN | c.10360+4436C>T | Intron (SNP) | VAF 36/69 reads (52%) | catalogued as rs369566893; called by muse, mutect2, varscan2
- WDR74 | c.65-29C>T | Intron (SNP) | VAF 107/207 reads (52%) | called by muse, mutect2, varscan2
